Gene-level copy-number profile of tumor specimen TCGA-CQ-7065-01A from TCGA case TCGA-CQ-7065, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 40.2 years (14,676 days).
Specimen TCGA-CQ-7065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.366f6301-0b53-422c-9947-c99c36404957.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-7065-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b5ec5139-7c3c-401a-b11c-e94af56469b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 141; copy number 1: 8,813; copy number 2: 43,694; copy number 3: 6,879; copy number 4: 167; copy number 5: 102; copy number 7: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-7065-01A-11D-2077-01): tumor purity 0.75, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 141 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr9:38,147,428–43,045,120, 140 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 119 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:72,782,133–73,016,461, 1 gene, copy number 7 (within-gene range 1–7): PIBF1.
- chr13:73,036,401–74,830,080, 22 genes, copy number 5–7: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1.
- chr13:85,046,001–85,148,121, 3 genes, copy number 7: AL356313.1, LINC00375, AL160154.1.
- chr21:33,229,901–34,784,886, 42 genes, copy number 5: IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1, KCNE1, AP000324.1, RCAN1, CLIC6, LINC00160, LINC01426.
- chr21:34,836,286–35,139,222, 2 genes, copy number 5: AP000331.1, AF015262.1.
- chr21:36,005,338–37,267,919, 49 genes, copy number 5 (within-gene range 3–5): LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.3, AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C.

Autosomal genes at a single copy (total copy number 1): 8,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
